CCDI case PBCCMA — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS.
https://portal.gdc.cancer.gov/cases/01895bd7-9969-42f6-aa32-a682dd1fc23d

Demographics
Sex at birth: male; Race: white.

Diagnoses (1)
1. Myofibroblastic tumor, NOS: ICD-O-3 morphology code: 8825/1; Tissue or organ of origin: Abdomen, NOS; Age at diagnosis: 14.3 years (5,230 days).

Biospecimens (3 samples)
- Sample 0DOJUW: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DOJXU: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
- Sample 0DOJY7: Tissue type: Tumor; Specimen type: Solid Tissue.
